Somatic mutation profile of tumor specimen TCGA-G4-6306-01A (aliquot TCGA-G4-6306-01A-11D-1771-10) from TCGA case TCGA-G4-6306, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; Age at diagnosis: 71.6 years (26,163 days).
Specimen TCGA-G4-6306-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a813538c-a1df-4ee0-bd7a-8e5665d06ae1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G4-6306-10A (Blood Derived Normal), aliquot TCGA-G4-6306-10A-01D-1771-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/232f9c06-3c7c-4731-afc8-7453cce46258

The open-access MAF lists 129 somatic variants for this specimen: 96 protein-altering or splice-affecting, 30 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 81, Silent 30, Nonsense Mutation 8, Frame Shift Del 3, In Frame Del 2, RNA 1, 5'Flank 1, Splice Region 1, 3'UTR 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2626C>T p.R876* | Nonsense Mutation (SNP) | VAF 16/45 reads (36%) | hotspot (GDC flag); catalogued as rs121913333, CM942020, COSV57320538; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 51/112 reads (46%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- GSN | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121909715, CM910196, CM920315, COSV57996695; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.1508G>T p.G503V | Missense Mutation (SNP) | VAF 161/179 reads (90%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397507546, CM086897, CM115675, CM1314033, COSV61004973, COSV61005158, COSV61008174; ClinVar: other / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 33/48 reads (69%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACD | c.1409C>T p.P470L (on ENST00000620338; = p.P381L on NM_022914.3) | Missense Mutation (SNP) | VAF 50/101 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs781117606, COSV54670973; called by muse, mutect2, varscan2
- ADGRB3 | c.2593C>A p.Q865K | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.93); PolyPhen benign (0.031); catalogued as COSV99483305; called by muse, mutect2, varscan2
- AFF2 | c.2977A>G p.T993A | Missense Mutation (SNP) | VAF 37/187 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.024); catalogued as COSV54011090; called by muse, mutect2, varscan2
- AP5B1 | c.1993C>T p.R665W | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs867398419, COSV57504965; called by muse, mutect2, varscan2
- APC | c.1918C>T p.R640W | Missense Mutation (SNP) | VAF 73/197 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1114167575, CS090535, COSV57337834; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARPP21 | c.1145C>T p.A382V | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as rs199754646, COSV51799772; called by muse, mutect2, varscan2
- ATP8B1 | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 49/86 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs757077093, COSV99376766; called by muse, mutect2, varscan2
- BMERB1 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 85/161 reads (53%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV55513648; called by muse, mutect2, varscan2
- C12orf50 | c.1022C>G p.A341G | Missense Mutation (SNP) | VAF 58/431 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as COSV53899804; called by muse, mutect2, varscan2
- CACNA2D3 | c.432T>A p.N144K | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.731); catalogued as COSV55589697; called by muse, mutect2, varscan2
- CCDC60 | c.818G>A p.S273N | Missense Mutation (SNP) | VAF 25/35 reads (71%) | SIFT tolerated (0.19); PolyPhen benign (0.215); catalogued as COSV100554885, COSV59552269; called by muse, mutect2, varscan2
- CDH22 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 34/248 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779360444, COSV64840016; called by muse, mutect2, varscan2
- CELSR1 | c.8657C>A p.T2886N | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.962); catalogued as COSV53101877; called by muse, mutect2, varscan2
- CFAP46 | c.488T>C p.L163P | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV63955588; called by muse, mutect2, varscan2
- CNBD1 | c.204G>T p.K68N | Missense Mutation (SNP) | VAF 24/344 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.946); catalogued as COSV72917698; called by muse, mutect2
- COL5A2 | c.1184G>A p.R395Q | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs766119748, COSV66406860; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPSF2 | c.10A>G p.I4V | Missense Mutation (SNP) | VAF 55/149 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.263); catalogued as rs777562704, COSV54100089; called by muse, mutect2, varscan2
- CPSF4 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 53/206 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52859473; called by muse, mutect2, varscan2
- CRHBP | c.203G>A p.G68D | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1347046951, COSV57190371; called by muse, mutect2, varscan2
- CSNK1G1 | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 74/232 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.246); catalogued as rs1337451905, COSV57313321; called by muse, mutect2, varscan2
- CTNND2 | c.2520G>T p.M840I | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV58870486; called by muse, mutect2, varscan2
- CUEDC1 | c.958_961del p.F320Nfs*12 | Frame Shift Del (DEL) | VAF 23/87 reads (26%) | catalogued as rs776086737; called by mutect2, pindel, varscan2
- CYFIP2 | c.3126G>T p.E1042D (on ENST00000616178 / NM_001291722.2; = p.E1017D on NM_014376.4) | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.234); catalogued as COSV59053790; called by muse, mutect2, varscan2
- CYP4F8 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 83/194 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.035); catalogued as rs374724909; called by muse, mutect2, varscan2
- DIAPH3 | c.3336G>T p.Q1112H | Missense Mutation (SNP) | VAF 98/488 reads (20%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as COSV64968426; called by muse, mutect2, varscan2
- DLGAP1 | c.2430G>A p.W810* | Nonsense Mutation (SNP) | VAF 48/143 reads (34%) | catalogued as COSV59843393; called by muse, mutect2, varscan2
- ELF3 | c.92del p.P31Lfs*12 | Frame Shift Del (DEL) | VAF 32/98 reads (33%) | catalogued as COSV62837797; called by mutect2, pindel, varscan2
- ELMO1 | c.139G>T p.E47* | Nonsense Mutation (SNP) | VAF 19/95 reads (20%) | catalogued as COSV60306554, COSV60329494; called by muse, mutect2, varscan2
- ENHO | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV54285584; called by muse, mutect2, varscan2
- FADS3 | c.607G>A p.V203M | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs767888295, COSV53878336; called by muse, mutect2, varscan2
- FAM114A1 | c.1450A>G p.K484E | Missense Mutation (SNP) | VAF 85/268 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as COSV62675413; called by muse, mutect2, varscan2
- FAM117A | c.620G>T p.S207I | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV53634430; called by muse, mutect2, varscan2
- FANCD2 | c.1916T>C p.I639T | Missense Mutation (SNP) | VAF 68/569 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV99810236; called by muse, varscan2
- FCRL3 | c.1247G>T p.R416L | Missense Mutation (SNP) | VAF 55/143 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.101); catalogued as COSV100942769, COSV63839727; called by muse, mutect2, varscan2
- FGF12 | c.133G>A p.V45I | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs766226672, COSV53167538; called by muse, mutect2, varscan2
- FOXRED2 | c.504G>T p.Q168H | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.094); catalogued as COSV53401864; called by muse, mutect2, varscan2
- GAB3 | c.1760G>C p.*587Sext*54 | Nonstop Mutation (SNP) | VAF 70/268 reads (26%) | catalogued as COSV65820992; called by muse, mutect2, varscan2
- GFPT2 | c.1882A>G p.S628G | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV53813394; called by muse, mutect2, varscan2
- HERC2 | c.8143C>T p.P2715S | Missense Mutation (SNP) | VAF 57/287 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99870569; called by muse, mutect2, varscan2
- HK3 | c.217C>T p.R73W | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs373192953; called by muse, mutect2, varscan2
- HMX2 | c.626C>T p.S209L | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV60593875; called by muse, mutect2, varscan2
- HPSE2 | c.1682G>A p.R561H | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as rs751015169, COSV65186620; called by muse, mutect2, varscan2
- IFNA7 | c.467A>G p.E156G | Missense Mutation (SNP) | VAF 114/322 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.141); catalogued as rs377239976, COSV53332545; called by muse, varscan2
- KIFC1 | c.655C>T p.R219W | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs570330144, COSV65737983; called by muse, mutect2, varscan2
- KRT74 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.035); catalogued as rs367926319; called by muse, mutect2, varscan2
- KRT76 | c.1267G>T p.A423S | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.673); catalogued as COSV100195846; called by muse, mutect2, varscan2
- LRRC14B | c.818G>A p.R273Q | Missense Mutation (SNP) | VAF 19/172 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.014); catalogued as rs748490211, COSV99359725; called by muse, mutect2, varscan2
- MED25 | c.869A>G p.E290G | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57208033; called by muse, mutect2, varscan2
- MTCL1 | c.2065G>A p.G689R (on ENST00000306329 / NM_001378206.1; = p.G329R on NM_015210.4) | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); catalogued as rs766408369, COSV60404283; called by muse, mutect2, varscan2
- MYH3 | c.2531C>T p.A844V | Missense Mutation (SNP) | VAF 120/240 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.077); catalogued as rs1035337949, COSV56871032; called by muse, mutect2, varscan2
- NAV3 | c.5500G>A p.A1834T (on ENST00000397909 / NM_001024383.2; = p.A1812T on NM_014903.6) | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.114); catalogued as COSV57117997; called by muse, mutect2, varscan2
- NEUROD2 | c.332T>C p.M111T | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.599); catalogued as COSV56911966; called by muse, mutect2, varscan2
- NIN | c.3107G>T p.C1036F | Missense Mutation (SNP) | VAF 36/208 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.387); catalogued as rs532449776, COSV55409595; called by muse, mutect2, varscan2
- NLRP3 | c.502C>T p.R168* | Nonsense Mutation (SNP) | VAF 40/101 reads (40%) | catalogued as rs746159202, COSV100275560, COSV60223782; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NOL6 | c.2351C>T p.T784M | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.928); catalogued as rs763014336, COSV53046612; called by muse, mutect2, varscan2
- PCDHA12 | c.2164C>T p.R722C | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as rs1554169939, COSV56554353; called by muse, mutect2, varscan2
- PCDHGA3 | c.85G>A p.G29S | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.248); catalogued as COSV53987248, COSV99545440; called by muse, mutect2, varscan2
- PCDHGB4 | c.2026C>T p.R676C | Missense Mutation (SNP) | VAF 75/171 reads (44%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.489); catalogued as rs1417147488, COSV53967357; called by muse, mutect2, varscan2
- PGK2 | c.409G>T p.G137* | Nonsense Mutation (SNP) | VAF 85/250 reads (34%) | catalogued as COSV59165984; called by muse, mutect2, varscan2
- PIP5K1C | c.1897G>A p.A633T | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); catalogued as rs769506439, COSV58956663; called by muse, mutect2, varscan2
- PLA1A | c.888C>A p.C296* | Nonsense Mutation (SNP) | VAF 78/227 reads (34%) | catalogued as COSV99845666; called by muse, mutect2, varscan2
- PRDM10 | c.1210C>T p.R404W | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760983714, COSV58802131; called by muse, mutect2, varscan2
- PRRT2 | c.270C>A p.S90R | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.12); catalogued as COSV54887427; called by muse, mutect2, varscan2
- PRRT2 | c.271C>A p.P91T | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.62); catalogued as COSV54887440; called by muse, mutect2, varscan2
- RAP1GAP2 | c.168G>A p.S56= | Splice Region (SNP) | VAF 96/154 reads (62%) | catalogued as rs753861727, COSV54590794; called by muse, mutect2, varscan2
- RGS4 | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs771715416, COSV63357940; called by muse, mutect2, varscan2
- SALL3 | c.3023C>T p.A1008V | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.146); catalogued as rs760077198, COSV73306213; called by muse, mutect2, varscan2
- SCN2A | c.159C>A p.N53K | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.41); catalogued as COSV51858297; called by muse, mutect2, varscan2
- SGSM3 | c.1964G>A p.R655H | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs763175054, COSV50655576; called by muse, mutect2, varscan2
- SIGLEC9 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs759377738, COSV51583448; called by muse, varscan2
- SLC26A11 | c.1258G>A p.D420N | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs371059198; called by muse, mutect2, varscan2
- SPIDR | c.1360C>T p.R454C | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs777715546, COSV52384134; called by muse, mutect2, varscan2
- TAF6L | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 53/161 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.011); catalogued as rs138817605; called by muse, mutect2, varscan2
- TMPRSS11D | c.942A>C p.Q314H | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs202115417, COSV52227073; called by muse, mutect2
- TMPRSS11D | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as rs760967680, COSV52227086; called by muse, mutect2, varscan2
- TRPA1 | c.1139A>G p.H380R | Missense Mutation (SNP) | VAF 36/618 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.237); catalogued as COSV100083027; called by muse, mutect2
- TRRAP | c.4082C>T p.S1361L | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV100722533, COSV62856378; called by muse, mutect2
- TSPY2 | c.518T>C p.I173T | Missense Mutation (SNP) | VAF 36/50 reads (72%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.9); catalogued as COSV57837381; called by muse, mutect2, varscan2
- TUSC3 | c.196T>G p.F66V | Missense Mutation (SNP) | VAF 61/79 reads (77%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV65879134, COSV65887519; called by muse, mutect2, varscan2
- UNC13C | c.6085A>G p.I2029V | Missense Mutation (SNP) | VAF 71/172 reads (41%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.681); catalogued as rs1169262936, COSV52933624; called by muse, mutect2, varscan2
- UNC79 | c.5803G>A p.A1935T (on ENST00000393151 / NM_001346218.2; = p.A1758T on NM_020818.5) | Missense Mutation (SNP) | VAF 54/163 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.012); catalogued as rs751743820, COSV56416742; called by muse, mutect2, varscan2
- ZIC3 | c.620C>T p.T207M | Missense Mutation (SNP) | VAF 35/38 reads (92%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.732); catalogued as COSV54977654; called by muse, mutect2, varscan2
- ZNF808 | c.1589G>A p.R530H | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as rs376417824; called by muse, mutect2, varscan2
- ZNF821 | c.890G>T p.R297L (on ENST00000425432 / NM_001376297.1; = p.R255L on NM_017530.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.982); catalogued as rs761280650, COSV100546702; called by muse, mutect2, varscan2
- ZNF835 | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.578); catalogued as rs746101788, COSV73379275; called by muse, mutect2, varscan2
- ZNF91 | c.3055G>T p.E1019* | Nonsense Mutation (SNP) | VAF 13/33 reads (39%) | catalogued as COSV56082238, COSV56095076; called by muse, mutect2, varscan2
- ZP2 | c.635A>G p.D212G | Missense Mutation (SNP) | VAF 50/200 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.53); catalogued as COSV54817512; called by muse, mutect2, varscan2
- F2RL3 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, varscan2
- SLC5A6 | c.1538_1540del p.F513del | In Frame Del (DEL) | VAF 16/55 reads (29%) | called by mutect2, pindel, varscan2
- SOX9 | c.1343_1344del p.S448* | Frame Shift Del (DEL) | VAF 23/79 reads (29%) | called by mutect2, pindel, varscan2
- ZDBF2 | c.934_939del p.K312_T313del | In Frame Del (DEL) | VAF 23/75 reads (31%) | called by mutect2, pindel, varscan2
- ACAD11 | c.490C>T p.L164= | Silent (SNP) | VAF 63/172 reads (37%) | catalogued as COSV53902717; called by muse, mutect2, varscan2
- ADGRB1 | c.3363C>T p.D1121= | Silent (SNP) | VAF 379/531 reads (71%) | catalogued as rs770062634, COSV60104145; called by muse, mutect2, varscan2
- ALDH1L1 | c.2388C>T p.D796= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV56420323; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.2028A>G p.A676= | Silent (SNP) | VAF 63/155 reads (41%) | catalogued as COSV51860836; called by muse, mutect2, varscan2
- ANKRD53 | c.675C>T p.D225= | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as COSV55539838; called by muse, mutect2, varscan2
- DAPK1 | c.1444C>T p.L482= | Silent (SNP) | VAF 31/78 reads (40%) | catalogued as COSV63792797; called by muse, mutect2, varscan2
- EPHB1 | c.117G>A p.A39= | Silent (SNP) | VAF 43/142 reads (30%) | catalogued as rs762148161, COSV67673823; called by muse, mutect2, varscan2
- GLI3 | c.3765G>A p.G1255= | Silent (SNP) | VAF 59/101 reads (58%) | catalogued as rs552476301, COSV67895993; called by muse, mutect2, varscan2
- GRIN2A | c.306C>T p.D102= | Silent (SNP) | VAF 21/100 reads (21%) | catalogued as rs200850130; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- HECW1 | c.1734G>A p.A578= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV67840222; called by muse, mutect2, varscan2
- HPSE2 | c.705C>A p.S235= | Silent (SNP) | VAF 19/156 reads (12%) | catalogued as COSV100984795; called by muse, mutect2, varscan2
- INSC | c.1083C>T p.H361= | Silent (SNP) | VAF 37/109 reads (34%) | catalogued as COSV65413731; called by muse, mutect2, varscan2
- KALRN | c.7323G>A p.T2441= (on ENST00000360013 / NM_001024660.4; = p.T744= on NM_007064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 84/248 reads (34%) | catalogued as rs371007725; called by muse, mutect2, varscan2
- LMO7 | c.4869G>A p.L1623= (on ENST00000357063; = p.L1304= on NM_005358.5) | Silent (SNP) | VAF 61/333 reads (18%) | catalogued as COSV100412351; called by muse, mutect2, varscan2
- NAV3 | c.3618C>T p.V1206= | Silent (SNP) | VAF 100/174 reads (57%) | catalogued as COSV57117975; called by muse, mutect2, varscan2
- NOTCH1 | c.621C>T p.R207= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs756164624, COSV53046556; ClinVar: likely benign; called by muse, varscan2
- NT5DC2 | c.1140C>T p.P380= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs752537469, COSV100194487; called by muse, mutect2, varscan2
- OR14A16 | c.594C>A p.I198= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as COSV62927634; called by muse, mutect2, varscan2
- OR2A42 | c.243G>A p.L81= | Silent (SNP) | VAF 29/203 reads (14%) | catalogued as rs376416848; called by muse, mutect2, varscan2
- PCDHA8 | c.714T>C p.N238= | Silent (SNP) | VAF 47/113 reads (42%) | catalogued as rs1554138741, COSV65340995; called by muse, mutect2, varscan2
- PLEKHG2 | c.2442G>A p.A814= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as rs750867855, COSV52677653, COSV52691215; called by muse, mutect2, varscan2
- PM20D2 | c.480A>T p.G160= | Silent (SNP) | VAF 70/154 reads (45%) | catalogued as COSV51532370; called by muse, mutect2, varscan2
- PRKCA | c.405C>T p.C135= | Silent (SNP) | VAF 27/85 reads (32%) | catalogued as rs748433014, COSV52590401; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC25A21 | c.768A>G p.T256= | Silent (SNP) | VAF 58/148 reads (39%) | catalogued as COSV100490213; called by muse, mutect2, varscan2
- SOX5 | c.1749C>T p.N583= | Silent (SNP) | VAF 152/297 reads (51%) | catalogued as COSV58651955; called by muse, mutect2, varscan2
- STYXL2 | c.2010C>T p.S670= | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as rs200893444; called by mutect2, varscan2
- THSD7B | c.1281G>A p.T427= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as rs563732139, COSV55693111, COSV99760095; called by muse, mutect2, varscan2
- TRAF1 | c.1071C>T p.H357= | Silent (SNP) | VAF 29/83 reads (35%) | catalogued as rs377159992; called by muse, mutect2, varscan2
- TTN | c.52779G>T p.V17593= (on ENST00000591111; = p.V10169= on NM_003319.4) | Silent (SNP) | VAF 72/189 reads (38%) | catalogued as COSV60191053, COSV60409921; called by muse, mutect2, varscan2
- ZNF697 | c.1215C>T p.G405= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as COSV70284377; called by muse, mutect2, varscan2
- CDRT15P3 | n.532G>C | RNA (SNP) | VAF 29/72 reads (40%) | catalogued as rs779206913; called by muse, mutect2, varscan2
- CTAG2 | c.*73G>T | 3'UTR (SNP) | VAF 437/555 reads (79%) | catalogued as COSV99908741, COSV99908877; called by muse, mutect2, varscan2
- DNAH8 | chr6:38722834 G>A | 5'Flank (SNP) | VAF 11/28 reads (39%) | catalogued as rs1476379780, COSV59482916; called by muse, mutect2, varscan2
